MMRF case MMRF_1073 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a2e0188e-8fca-4a4e-9da5-69ae7c2c68d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.3 years (22,748 days); ISS stage: I; Days to last known disease status: 1,751 days (4.8 years); Days to last follow up: 1,751 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 139 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 265 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): M Protein 5.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 79.1 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.31 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 11.4 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.093 mg/dL.
- Day 96 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 5.09 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.48 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.35 mmol/L.
- Day 168 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.32 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.66 mmol/L.
- Day 265 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.015 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.017 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.28 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 37.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 363 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 6 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Glucose 3.63 mmol/L.
- Day 447: Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 31.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Glucose 4.07 mmol/L.
- Day 496: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.57 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 6.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 29.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Glucose 4.79 mmol/L.
- Day 566: Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 5.5 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 36.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 44.1 g/L; Total Protein 7.1 g/dL; Glucose 4.84 mmol/L.
- Day 657 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 6.46 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.53 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 39.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 3.91 mmol/L.
- Day 741 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 6.42 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 31.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 3.63 mmol/L.
- Day 860 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.74 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 916 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 3.91 mmol/L.
- Day 1,000 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.081 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.139 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.46 mmol/L.
- Day 1,091 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.122 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.167 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 1,238 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.82 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.
- Day 1,293: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.151 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.188 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.24 mmol/L.
- Day 1,411: Hemoglobin 7.69 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 194 ×10⁹/L.
- Day 1,497: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.29 mmol/L.
- Day 1,595: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 8.11 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.32 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 1,665 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 8.12 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 3.7 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 1,751: Hemoglobin 7.63 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -8: Weight: 52 kg; Height: 154 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1073_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1073_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 860 days (2.4 years).
